Somatic mutation profile of tumor specimen HCM-CSHL-0403-C25-01B (aliquot HCM-CSHL-0403-C25-01B-01D-A85K-36) from HCMI case HCM-CSHL-0403-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.9 years (23,352 days).
Specimen HCM-CSHL-0403-C25-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f434151f-5c0a-4d5c-988c-28323c650934.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0403-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0403-C25-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d424bfe-5d84-4d4d-a01b-15a813caf00a

The open-access MAF lists 33 somatic variants for this specimen: 28 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 3, Nonsense Mutation 1, Intron 1, Frame Shift Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 55/326 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.643A>C p.S215R | Missense Mutation (SNP) | VAF 28/193 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039484, CD1511147, COSV52675946, COSV52689203, COSV52876251, COSV53707934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY5 | c.3164G>A p.R1055H | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs762578500, COSV59201616; called by muse, mutect2, varscan2
- CDKN2A | c.278C>G p.T93R | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876659723, COSV58684508, COSV58684689, COSV58721866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELMO1 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1329010889; called by muse, mutect2, varscan2
- HAP1 | c.1457C>T p.T486M (on ENST00000310778 / NM_001367460.1; = p.T434M on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs782546957, COSV57880158; called by muse, mutect2
- MAGEB6B | c.312A>T p.Q104H | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.455); catalogued as rs878898788; called by muse, mutect2, varscan2
- MYO15A | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1248557646, COSV52760772, COSV52769060; called by muse, mutect2, varscan2
- NALCN | c.3658G>A p.V1220I | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.699); catalogued as rs771258062; called by muse, mutect2, varscan2
- PEX14 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs770183471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PXDNL | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs766991284, COSV62488808; called by muse, mutect2, varscan2
- SLC12A3 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187885782, CM088242; called by muse, mutect2, varscan2
- ST8SIA1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV99683663; called by muse, mutect2, varscan2
- TLE4 | c.1551C>A p.H517Q | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1337584176; called by muse, mutect2, varscan2
- TMCO4 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 24/150 reads (16%) | catalogued as rs369962324; called by muse, mutect2, varscan2
- TSPAN10 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs771337272, COSV100148454; called by muse, mutect2, varscan2
- UNC5B | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs200337007; called by muse, mutect2, varscan2
- ZNF843 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.111); catalogued as rs902170193, COSV59848266; called by muse, mutect2, varscan2
- COL1A2 | c.3533A>T p.Y1178F | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EFCAB8 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- GPRIN3 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.045); called by mutect2, varscan2
- IGHV1-69 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, varscan2
- LRRC9 | c.2590C>T p.P864S | Missense Mutation (SNP) | VAF 56/328 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NACAD | c.2264C>T p.T755I | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, varscan2
- PNPO | c.104G>C p.G35A | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RALGAPA2 | c.1620dup p.A541Cfs*3 | Frame Shift Ins (INS) | VAF 37/335 reads (11%) | called by mutect2, varscan2
- TBL2 | c.222A>C p.Q74H | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TGFBR2 | c.325_332del p.H109Yfs*20 | Frame Shift Del (DEL) | VAF 42/260 reads (16%) | called by mutect2, varscan2
- AMPD3 | c.729G>A p.P243= (on ENST00000396553 / NM_001025389.2; = p.P252= on NM_000480.3) | Silent (SNP) | VAF 27/233 reads (12%) | catalogued as rs780910038; called by muse, mutect2, varscan2
- C5orf38 | c.99G>A p.P33= | Silent (SNP) | VAF 30/193 reads (16%) | catalogued as COSV57412608; called by muse, mutect2, varscan2
- DMRTC2 | c.655C>T p.L219= | Silent (SNP) | VAF 26/201 reads (13%) | called by muse, varscan2
- NEB | c.11601+6151C>T | Intron (SNP) | VAF 46/512 reads (9%) | catalogued as rs775872152; called by muse, varscan2
- ULBP3 | c.*1G>A | 3'UTR (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2
